Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4325, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4325-01A (Primary Tumor).

[page 1 of 3]
Other Related Data:

Billing Type:

INPATIENT

Financial Number:

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

- 1: SP: Left kidney
- 2: SP: Portion of left 11th rib
- 3: SP: Peri-hilar tissue
- 4: SP: Left adrenal gland

DIAGNOSIS:

- 1) KIDNEY, LEFT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV.
- THE TUMOR'S GREATEST DIAMETER IS 4.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL CHRONIC INFLAMMATION ONLY.
- 2) RIB, LEFT 11TH; PARTIAL EXCISION:
- BENIGN CARTILAGE AND CONNECTIVE TISSUE.
- 3) SOFT TISSUE, LEFT RENAL, PERIHILAR; EXCISION:
- BENIGN MICROSCOPIC LYMPH NODE AND FIBROADIPOSE TISSUE.
- 4) ADRENAL GLAND, LEFT; EXCISION:
- UNREMARKABLE ADRENAL GLAND.

Gross Description:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

1) The specimen is received fresh, labeled "Kidney". It consists of a 11 x 8 x 4.5 cm total nephrectomy, with a 6 cm long unremarkable ureter with a diameter of 5 mm. The kidney is covered with fatty tissue. No adrenal gland is received within the specimen. Upon sectioning a 4.5 x 3.5 x 3 cm, bright yellow, ovoid tumor mass with central area of white-gray, glistening changes. The tumor occupies the upper pole of the kidney, bulges out beyond the cortex, but remains confined to the renal capsule. The hilar aspect of the tumor shows possible involvement of the peripelvic fatty tissue. The remainder of the kidney is unremarkable. The pelvic lining is tan, glistening and shows no lesions. The renal vein is unremarkable and no tumor involvement is appreciated. A small fresh sample is obtained for TPS.

Summary of Sections:

UM - urethral margin
T - tumor in relation to renal capsule and hilar area
RK - random kidney
PM - pelvic mucosa

2) The specimen is received in formalin, labeled "Portion of left 11th rib". It consists of a 2.5 x 1.0 x 1.0 cm portion of unremarkable rib. The specimen is serially sectioned. Representative sections of the specimen are submitted in one cassette after decalcification.

Summary of Sections:

U - undesignated

3) The specimen is received fresh, labeled "Peri-hilar tissue". It consists of a 2.0 x 2.0 x 1.0 cm, unremarkable, fatty tissue.

Summary of Sections:

U - undesignated

4) The specimen is received fresh, labeled "Left adrenal gland". It consists of a 4.0 x 1.0 x 1.0 cm complete adrenal gland with unremarkable cut section. It is surrounded with unremarkable fatty tissue. Representative sections of the specimen are submitted in two cassettes.

Summary of Sections:

U - undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	PM		1	1	N
	RK		1	1	
	T		7	7	
	UM		1	1	

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

2	U	1	-	N
3	U	1	1	Y
4	U	2	2	N

Source: NCI Genomic Data Commons file d3c7ca3d-5c23-4098-aa23-fe1aff954860 (TCGA-BP-4325.0C32E453-66E4-49AD-B0E8-4402BB340B9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).